MMRF case MMRF_1534 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8165e3bf-4cef-427a-8a86-884a2269633e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.2 years (23,435 days); ISS stage: I; Days to last known disease status: 1,248 days (3.4 years); Days to last follow up: 1,248 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 76 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 15 days; Days to treatment end: 76 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 138 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 163 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 163 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 238 days; Days to treatment end: 928 days (2.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 947 days (2.6 years); Days to treatment end: 1,101 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,122 days (3.1 years); Days to treatment end: 1,290 days (3.5 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,331 days (3.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -35: M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 237 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 5.51 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.54 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 0.97 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 6.82 mmol/L; C-Reactive Protein 0.1 mg/dL.
- Day 51: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 3.74 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 1.63 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 1.6 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 5.9 g/dL; Glucose 6.27 mmol/L.
- Day 151 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 4.57 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 6.77 mmol/L.
- Day 234: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.44 mg/dL; Immunoglobulin G 5.94 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.62 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.05 mmol/L.
- Day 322: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.985 mg/dL; Immunoglobulin G 5.72 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.6 µg/mL; Hemoglobin 7.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 5.4 g/dL; Glucose 4.24 mmol/L.
- Day 406 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 7.38 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Total Protein 5.9 g/dL; Glucose 4.73 mmol/L.
- Day 486 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 7.5 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.98 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.5 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.07 mmol/L.
- Day 595: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.86 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.8 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 150 µmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.
- Day 665: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 9.31 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.3 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 133 µmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 731 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 8.04 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.89 mmol/L.
- Day 875 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 8.49 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.03 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 5.34 mmol/L.
- Day 947 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 8.34 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 8.69 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.1 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 6.88 mmol/L.
- Day 1,044 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.66 mg/dL; Immunoglobulin G 8.11 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 1,122 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 30.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 7.45 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.22 mmol/L.
- Day 1,248 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 37.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 3.98 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.32 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -35: Weight: 81 kg; Height: 181 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1534_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -35 days.
- Sample MMRF_1534_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -35 days.
